Surgical pathology report (de-identified scan), TCGA case TCGA-D1-A165, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site Mayo Clinic, specimen TCGA-D1-A165-01A (Primary Tumor).

[page 1 of 3]
1CD-0-3

Adenocarcinoma, Endometrioid, NOS

8380/3 12/9/10
sw

Surgical Pathology Site Code: Endometrium C54.1

TISSUE DESCRIPTION:

A1 A2 B1 B2 B3 C1 C2 C3 C4 C5 C6 C7 D1 D2 D3 D4
D5 D6 D7
D8 E1 E2 E3 E4 E5 E6 E7 E8 E9 E10 E11
Uterus, right ovary (3.2 x 1.2 x 0.8 cm) with 7.8 cm
segment of
right fallopian tube, and left ovary (2.2 x 1.5 x 0.8 cm)
with 6.5
cm segment of left fallopian tube together weighing 110.0
grams,
right and left pelvic lymph nodes, right and left para-
aortic lymph
nodes.

DIAGNOSIS:

Uterus, endometrium, hysterectomy: Endometrial
adenocarcinoma,
endometrioid type, FIGO grade 1 (of 3) forming a 2.0 x 2.0
x 1.0 cm
mass. The tumor invades 0.5 cm into a 2.0 cm thick
myometrium. The background endometrium shows complex
hyperplasia with atypia. There is no lymphovascular
invasion. The
cervix is uninvolved.

Ovaries, right and left, oophorectomies: The bilateral
ovaries show
cortical inclusion cysts.

Fallopian tubes, right and left, salpingectomies:
Bilateral
fallopian tubes reveal no diagnostic abnormalities.

Lymph nodes, right pelvic, excision: Multiple (13) right
pelvic
lymph nodes are negative for tumor.

Lymph nodes, left pelvic, excision: Multiple (17) left
pelvic lymph
nodes are negative for tumor.

Lymph nodes, right and left para-aortic lymph nodes,
excision:

[page 2 of 3]
Multiple (13) right and left para-aortic lymph nodes,
submitted as
one specimen, are negative for tumor.

AMENDMENTS: (Previous Signout Date:
Revision Description: In the Final Diagnosis, it should
state, "The
tumor invades 0.5 cm into a 2.0 cm thick myometrium." and
not
endometrium.
....Original Diagnosis....
Uterus, endometrium, hysterectomy: Endometrial
adenocarcinoma,
endometrioid type, FIGO grade 1 (of 3) forming a 2.0 x 2.0
x 1.0 cm
mass. The tumor invades 0.5 cm into a 2.0 cm thick
endometrium.
The background endometrium shows complex hyperplasia with
atypia.
There is no lymphovascular invasion. The cervix is
uninvolved.

Ovaries, right and left, oophorectomies: The bilateral
ovaries show
cortical inclusion cysts.

Fallopian tubes, right and left, salpingectomies:
Bilateral
fallopian tubes reveal no diagnostic abnormalities.

Lymph nodes, right pelvic, excision: Multiple (13) right
pelvic
lymph nodes are negative for tumor.

Lymph nodes, left pelvic, excision: Multiple (17) left
pelvic lymph
nodes are negative for tumor.

Lymph nodes, right and left para-aortic lymph nodes,
excision:
Multiple (13) right and left para-aortic lymph nodes,
submitted as
one specimen, are negative for tumor.

[page 3 of 3]
....Original Gross Description....

Uterus, right ovary (3.2 x 1.2 x 0.8 cm) with 7.8 cm
segment of
right fallopian tube, and left ovary (2.2 x 1.5 x 0.8 cm)
with 6.5
cm segment of left fallopian tube together weighing 110.0
grams,
right and left pelvic lymph nodes, right and left para-
aortic lymph
nodes..

Source: NCI Genomic Data Commons file 8a13cfe8-1edc-412f-8962-cc083d407c57 (TCGA-D1-A165.476F8219-DAAE-4DB3-BA31-C64AC24ACF65.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).